Gene-level copy-number profile of tumor specimen MP2PRT-PATRPS-TBP1-A from MP2PRT case MP2PRT-PATRPS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,925 days).
Specimen MP2PRT-PATRPS-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file abe164ef-1946-4994-a44b-b05734b20350.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATRPS-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/8f713f4e-ee1a-47a3-8c7b-0ff7d09e00a3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 171; copy number 1: 176; copy number 2: 39,149; copy number 3: 1,905; copy number 4: 16,270; copy number 5: 2; copy number 6: 722.

Homozygous deletions (total copy number 0; autosomes only): 171 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,257,879–38,265,678, 1 gene (within-gene range 0–2): TRGC1.
- chr7:38,273,587–38,300,322, 5 genes (within-gene range 0–2): TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr9:61,190,003–61,582,675, 8 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3.
- chr14:22,438,547–22,439,015, 2 genes (within-gene range 0–2): TRDD1, TRDD2.
- chr14:105,672,308–106,631,653, 150 genes (within-gene range 0–4) (broad region; genes not listed).
- chr14:106,637,718–106,639,657, 2 genes (within-gene range 0–3): IGHVII-60-1, IGHV4-61.
- chr14:106,657,725–106,672,073, 3 genes (within-gene range 0–3): IGHV3-64, IGHV3-65, IGHVII-65-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 724 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:40,559,666–40,584,335, 2 genes, copy number 5: AL356379.2, AL356379.1.
- chr21:13,038,160–46,691,226, 722 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
